Somatic mutation profile of tumor specimen BA2645D (aliquot aq-BA2645D) from BEATAML1.0 case 2230, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute monoblastic and monocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 73.7 years (26,916 days).
Specimen BA2645D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f8adb51-a397-4cd0-bff9-c6822fc7d26e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2373D (Solid Tissue Normal), aliquot aq-BA2373D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/75456930-02fb-4620-ac60-dbbe03c0a454

The open-access MAF lists 26 somatic variants for this specimen: 16 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 5, Intron 3, Frame Shift Del 3, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SRSF2 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 47/113 reads (42%) | hotspot (GDC flag); SIFT tolerated (0.57); PolyPhen benign (0.398); catalogued as rs751713049, CM1511359, COSV57969809, COSV57969816, COSV57969830; called by muse, mutect2, varscan2
- CHD4 | c.3274C>T p.R1092W (on ENST00000357008 / NM_001363606.2; = p.R1105W on NM_001273.5) | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58898720; called by muse, mutect2, varscan2
- CRTAP | c.295G>T p.G99C | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as rs759181527; called by muse, mutect2, varscan2
- GLB1L2 | c.1403C>T p.T468M | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.34); catalogued as rs371241727; called by muse, mutect2, varscan2
- IMP3 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.035); catalogued as rs1264537483; called by muse, mutect2, varscan2
- IMPA2 | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.052); catalogued as rs1207114507, COSV52318869; called by muse, mutect2, varscan2
- POTEF | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 91/268 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs373400642; called by muse, mutect2, varscan2
- TET2 | c.1337del p.L446* | Frame Shift Del (DEL) | VAF 33/123 reads (27%) | catalogued as rs1334370179; called by mutect2, pindel, varscan2
- TET2 | c.2474del p.S825* | Frame Shift Del (DEL) | VAF 161/387 reads (42%) | catalogued as COSV54396396, COSV54408263, COSV54408885, COSV54430993; called by mutect2, varscan2
- DOCK4 | c.2947G>A p.V983I | Missense Mutation (SNP) | VAF 63/161 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ELMO2 | c.1062del p.F354Lfs*103 | Frame Shift Del (DEL) | VAF 27/73 reads (37%) | called by mutect2, pindel, varscan2
- MKI67 | c.3973A>C p.N1325H | Missense Mutation (SNP) | VAF 114/236 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, varscan2
- MYC | c.826A>G p.R276G (on ENST00000377970; = p.R291G on NM_002467.6) | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- NFATC2 | c.1019G>T p.G340V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.611); called by muse, mutect2
- PLA2G4E | c.886A>T p.S296C | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- VN1R2 | c.964A>C p.S322R | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FNDC1 | c.2388C>T p.D796= | Silent (SNP) | VAF 56/148 reads (38%) | catalogued as rs763282736, COSV51935875; called by muse, mutect2, varscan2
- MAGEB2 | c.351G>A p.S117= | Silent (SNP) | VAF 85/110 reads (77%) | catalogued as rs944047855; called by muse, mutect2, varscan2
- OR8K3 | c.603C>A p.I201= | Silent (SNP) | VAF 96/240 reads (40%) | catalogued as rs759558721, COSV57132313; called by muse, mutect2, varscan2
- POM121L12 | c.426G>A p.A142= | Silent (SNP) | VAF 66/166 reads (40%) | catalogued as COSV68692379; called by muse, mutect2, varscan2
- RBFOX1 | c.771G>A p.P257= | Silent (SNP) | VAF 34/75 reads (45%) | catalogued as rs916986800, COSV60959742; ClinVar: likely benign; called by muse, varscan2
- ARID5A | c.313-79T>C | Intron (SNP) | VAF 37/111 reads (33%) | called by muse, mutect2, varscan2
- FOXP2 | c.*3016C>T | 3'UTR (SNP) | VAF 164/402 reads (41%) | catalogued as rs548292791; called by muse, mutect2, varscan2
- NTRK3 | c.2133+12682C>T | Intron (SNP) | VAF 60/122 reads (49%) | called by muse, mutect2, varscan2
- SENP3 | c.716-178C>A | Intron (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- ZBTB37 | chr1:173866331 A>G | 5'Flank (SNP) | VAF 21/127 reads (17%) | catalogued as rs369212964; called by muse, mutect2, varscan2
